TCGA case TCGA-CR-6493 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b43b8aed-d166-4f00-8144-24ad3fe314ed

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 282 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.6 years (25,432 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 2; Lymph nodes tested: 16; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 100 days; Days to treatment end: 150 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 100 days; Days to treatment end: 150 days; Treatment dose: 7,000 cGy; Treatment outcome: Complete Response; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 150 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Gum, NOS. Age at diagnosis: 70.3 years (25,679 days); Days to diagnosis: 247 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 247 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Gum, NOS; Days to recurrence: 247 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 282 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1956; Tobacco smoking quit year: 1987.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-6493-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
  Slide TCGA-CR-6493-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-CR-6493-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 3; Alcohol history documented: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; Cause of death: Related to Head & Neck Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 282 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 282 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 247 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-6493-01A-11D-1869-01): tumor purity 0.67, ploidy 3.81, whole-genome doublings 1.
